Somatic mutation profile of tumor specimen 0DW6C8 from CCDI case PBCNVZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 18.7 years (6,818 days).
Specimen 0DW6C8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 683b588d-6198-4f60-b01f-f350af925350.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DW6B5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/200515ae-82ed-4d74-80d6-4aac9821e2ed

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NBN | c.1064G>A p.S355N | Missense Mutation (SNP) | VAF 133/2413 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55374627; called by muse, mutect2
- PHLDA2 | c.250T>A p.C84S | Missense Mutation (SNP) | VAF 64/626 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV56541966; called by muse, mutect2, varscan2
- SERPINB4 | c.835T>C p.C279R | Missense Mutation (SNP) | VAF 134/1067 reads (13%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs576273012, COSV61985381; called by muse, mutect2, varscan2
- AEBP2 | c.1259A>G p.E420G | Missense Mutation (SNP) | VAF 56/1166 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.986); called by muse, mutect2
- ARL6IP5 | c.157A>G p.M53V | Missense Mutation (SNP) | VAF 72/798 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- HMGCS2 | c.524A>G p.N175S | Missense Mutation (SNP) | VAF 18/676 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); called by muse, mutect2
- OTX1 | c.97G>T p.A33S | Missense Mutation (SNP) | VAF 50/610 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.118); called by muse, mutect2
- SACS | c.2102T>C p.F701S | Missense Mutation (SNP) | VAF 139/2126 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.124); called by muse, mutect2
- SASH1 | c.1166C>A p.T389N | Missense Mutation (SNP) | VAF 85/682 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- ABCA7 | c.6399C>T p.S2133= | Silent (SNP) | VAF 68/755 reads (9%) | called by muse, mutect2
- BPNT2 | c.63C>T p.L21= | Silent (SNP) | VAF 24/1020 reads (2%) | catalogued as rs1359487456; called by muse, mutect2
- OR10J4 | c.696G>A p.L232= | Silent (SNP) | VAF 30/1032 reads (3%) | called by muse, mutect2
- DST | c.4296+4345T>C | Intron (SNP) | VAF 40/1603 reads (2%) | called by muse, mutect2
- OLFM4 | c.*50C>T | 3'UTR (SNP) | VAF 41/419 reads (10%) | called by muse, mutect2
